Somatic mutation profile of tumor specimen ALCH-B1TR-TTP1-A (aliquot ALCH-B1TR-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1TR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 78.0 years (28,493 days).
Specimen ALCH-B1TR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be2f7e70-accd-4ba9-bd42-658455cb9605.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1TR-NB1-A (Blood Derived Normal), aliquot ALCH-B1TR-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84c60218-977e-4885-9956-6c5b858ceb7a

The open-access MAF lists 537 somatic variants for this specimen: 351 protein-altering or splice-affecting, 123 silent, 63 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 299, Silent 123, Nonsense Mutation 27, Intron 26, RNA 20, Frame Shift Del 11, Splice Site 7, 5'UTR 5, 5'Flank 5, Splice Region 5, 3'Flank 4, 3'UTR 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 195/577 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A2M | c.723C>G p.I241M | Missense Mutation (SNP) | VAF 12/460 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as rs1249029080, COSV100588873, COSV59388299; called by muse, mutect2
- AASDHPPT | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 72/443 reads (16%) | catalogued as COSV53789192; called by muse, mutect2, varscan2
- ADGRB3 | c.2467del p.D823Mfs*47 | Frame Shift Del (DEL) | VAF 28/155 reads (18%) | catalogued as COSV65390026, COSV65395815; called by mutect2, pindel, varscan2
- ADGRG4 | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 79/184 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs749849930; called by muse, mutect2, varscan2
- ADGRV1 | c.6730G>A p.V2244I | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.279); catalogued as rs759954556; called by muse, varscan2
- AKAP5 | c.1099G>C p.E367Q | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as COSV57742153; called by muse, varscan2
- AKAP8 | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 83/414 reads (20%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs767746415, COSV54102409; called by muse, mutect2, varscan2
- ALMS1 | c.2231C>T p.S744L | Missense Mutation (SNP) | VAF 24/354 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.149); catalogued as CM156207; called by muse, mutect2
- ANKRD36C | c.2342G>A p.G781E | Missense Mutation (SNP) | VAF 111/329 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1298096233; called by muse, mutect2, varscan2
- ARHGEF2 | c.2953G>A p.E985K (on ENST00000361247 / NM_001162383.2; = p.E957K on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as rs921566752; called by muse, mutect2, varscan2
- ASTN1 | c.1397G>T p.R466L | Missense Mutation (SNP) | VAF 88/423 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99920549; called by muse, mutect2, varscan2
- AXIN1 | c.2558_2560del p.K853del | In Frame Del (DEL) | VAF 132/512 reads (26%) | catalogued as rs1204980787; called by pindel, varscan2
- BCL11B | c.1585G>T p.E529* (on ENST00000357195 / NM_001282237.2; = p.E458* on NM_022898.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/318 reads (7%) | catalogued as COSV61737177; called by muse, mutect2
- BIRC6 | c.10063A>G p.T3355A | Missense Mutation (SNP) | VAF 45/464 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.199); catalogued as rs1412801038; called by muse, mutect2
- BOD1L1 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 40/633 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs147855039; called by muse, mutect2
- C1QL1 | c.658G>A p.V220M | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99492806; called by muse, mutect2
- CACNA1B | c.3969G>T p.R1323S | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV53142293; called by muse, mutect2
- CCDC158 | c.34G>T p.D12Y | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.191); catalogued as COSV63092560; called by muse, mutect2, varscan2
- CD93 | c.1820G>A p.R607H | Missense Mutation (SNP) | VAF 50/644 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs769815543, COSV55664313; called by muse, mutect2
- CERS5 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs147527651; called by muse, mutect2, varscan2
- CHRM3 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 26/228 reads (11%) | catalogued as COSV55085839; called by muse, mutect2, varscan2
- CNTN4 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 32/322 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765118168, COSV100638650; called by muse, mutect2
- CNTNAP4 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 57/461 reads (12%) | catalogued as COSV100273632; called by muse, mutect2, varscan2
- CNTNAP5 | c.2629G>A p.V877I | Missense Mutation (SNP) | VAF 45/605 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV70519201; called by muse, mutect2
- CRHBP | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 105/293 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.261); catalogued as rs1283436733; called by muse, mutect2, varscan2
- CSMD1 | c.4162A>G p.I1388V (on ENST00000520002; = p.I1387V on NM_033225.6) | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs538040776; called by muse, mutect2, varscan2
- CUL7 | c.4669G>A p.G1557S | Missense Mutation (SNP) | VAF 30/580 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as rs185741954, COSV99538969; called by muse, mutect2
- CYP2F1 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 16/583 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as COSV100462729; called by muse, mutect2
- DDX24 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 19/321 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV58211971; called by muse, mutect2
- DGKZ | c.2500C>T p.R834C (on ENST00000454345 / NM_001105540.2; = p.R646C on NM_003646.4) | Missense Mutation (SNP) | VAF 57/191 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1355423147; called by muse, mutect2, varscan2
- DLGAP1 | c.2371C>T p.R791W | Missense Mutation (SNP) | VAF 125/568 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs963376980; called by muse, mutect2, varscan2
- DNAH5 | c.9252T>G p.I3084M | Missense Mutation (SNP) | VAF 18/484 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as rs1318129305; called by muse, mutect2
- DNAH5 | c.1869C>G p.I623M | Missense Mutation (SNP) | VAF 166/778 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as COSV54204075; called by muse, mutect2, varscan2
- DSG3 | c.1117C>T p.Q373* | Nonsense Mutation (SNP) | VAF 35/391 reads (9%) | catalogued as rs778432093; called by muse, mutect2
- EDNRB | c.134G>T p.R45I | Missense Mutation (SNP) | VAF 46/356 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.03); catalogued as COSV100526843; called by muse, varscan2
- ELFN1 | c.1909C>T p.R637C | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1273292018; called by muse, mutect2
- ENPP7 | c.188A>T p.K63M | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1568484786; called by muse, mutect2, varscan2
- EP400 | c.2720C>A p.S907Y | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV57788721; called by muse, mutect2
- EYS | c.4902G>C p.K1634N | Missense Mutation (SNP) | VAF 59/339 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.38); catalogued as COSV58197228; called by muse, mutect2, varscan2
- EYS | c.4187C>G p.S1396C | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.887); catalogued as COSV58201658; called by muse, mutect2
- FAM131C | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1364072891; called by muse, mutect2
- FAM135B | c.3699C>A p.F1233L | Missense Mutation (SNP) | VAF 61/566 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV52703933, COSV52705298; called by muse, mutect2, varscan2
- FAM47C | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1412392577, COSV63726270; called by muse, mutect2, varscan2
- FANCE | c.1501C>G p.Q501E | Missense Mutation (SNP) | VAF 55/474 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs746321808; called by muse, mutect2, varscan2
- FAT4 | c.14798A>T p.D4933V | Missense Mutation (SNP) | VAF 94/570 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs901362094; called by muse, mutect2, varscan2
- FEZF1 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 21/273 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV58658149; called by muse, mutect2
- FLYWCH1 | c.2083T>C p.C695R (on ENST00000253928 / NM_001308068.2; = p.C694R on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV54149604; called by muse, mutect2
- FZR1 | c.457G>A p.V153I | Missense Mutation (SNP) | VAF 58/227 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs201109329, COSV100553888; called by muse, mutect2, varscan2
- GABRQ | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 38/349 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1343935503, COSV100941393; called by muse, varscan2
- GRID2IP | c.1432G>C p.E478Q | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.143); catalogued as rs1300077231; called by muse, mutect2, varscan2
- HAPLN4 | c.997G>T p.V333L | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.593); catalogued as COSV52271472; called by muse, mutect2, varscan2
- IFNA17 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 30/365 reads (8%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV69738280; called by muse, mutect2
- IL17RC | c.2221C>T p.R741C (on ENST00000295981 / NM_153461.4; = p.R655C on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/546 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1477967348; called by muse, mutect2, varscan2
- IL25 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs565998581, COSV59307001; called by muse, mutect2
- ITIH5 | c.1399G>T p.A467S | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs574389762; called by muse, mutect2, varscan2
- JPH2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 72/439 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.833); catalogued as COSV65902947, COSV65905090; called by muse, mutect2, varscan2
- KCNV1 | c.810C>A p.F270L | Missense Mutation (SNP) | VAF 19/215 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52087153; called by muse, mutect2
- KIR3DL2 | c.451G>C p.E151Q | Missense Mutation (SNP) | VAF 45/622 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs879153275; called by muse, mutect2
- KRT25 | c.432C>T p.I144= | Splice Region (SNP) | VAF 24/356 reads (7%) | catalogued as COSV56446394; called by muse, mutect2
- LATS2 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.119); catalogued as rs762240840, COSV66874894; called by muse, mutect2, varscan2
- LIFR | c.1462G>C p.E488Q | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.414); catalogued as rs1248323163; called by muse, mutect2, varscan2
- LMBR1L | c.296A>G p.Y99C | Missense Mutation (SNP) | VAF 65/530 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763409817; called by muse, mutect2, varscan2
- LMCD1 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 18/213 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as rs761878144, COSV50092939; called by muse, mutect2
- LPL | c.1003C>G p.Q335E | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT tolerated (0.85); PolyPhen benign (0.158); catalogued as COSV60932515; called by muse, mutect2
- LRBA | c.7826A>G p.Y2609C | Missense Mutation (SNP) | VAF 20/340 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); catalogued as rs371465105; called by muse, mutect2
- LRRTM4 | c.200C>A p.S67* | Nonsense Mutation (SNP) | VAF 126/383 reads (33%) | catalogued as rs377112975; called by muse, mutect2, varscan2
- LTBP3 | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 42/434 reads (10%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.877); catalogued as COSV57244376; called by muse, mutect2, varscan2
- MAPT | c.890G>A p.R297H (on ENST00000262410 / NM_001377265.1; = p.R222H on NM_016835.4) | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.933); catalogued as rs546607985; called by muse, mutect2, varscan2
- MBOAT7 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs758805684, COSV55476305; ClinVar: uncertain significance; called by muse, mutect2
- MC5R | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 67/252 reads (27%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100228971; called by muse, mutect2, varscan2
- MDN1 | c.15772C>T p.R5258* | Nonsense Mutation (SNP) | VAF 47/422 reads (11%) | catalogued as rs1311244151; called by muse, mutect2, varscan2
- MMEL1 | c.1351G>A p.V451M | Missense Mutation (SNP) | VAF 65/180 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139384428; called by muse, mutect2, varscan2
- MNDA | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 41/248 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs200188147, COSV63741498; called by muse, mutect2, varscan2
- MT2A | c.28G>T p.G10C | Missense Mutation (SNP) | VAF 108/345 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99803167; called by muse, mutect2, varscan2
- MUC4 | c.12049C>G p.L4017V | Missense Mutation (SNP) | VAF 38/664 reads (6%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.374); catalogued as rs761034521; called by muse, mutect2
- MYO1E | c.147+1G>A p.X49_splice | Splice Site (SNP) | VAF 53/442 reads (12%) | catalogued as rs565568548; called by muse, mutect2, varscan2
- MYO7A | c.5785C>G p.Q1929E | Missense Mutation (SNP) | VAF 245/440 reads (56%) | SIFT tolerated (0.41); PolyPhen benign (0.036); catalogued as CM163781; called by muse, mutect2, varscan2
- NBN | c.938C>A p.A313E | Missense Mutation (SNP) | VAF 92/337 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55376502; called by muse, mutect2, varscan2
- NCKAP5 | c.3462G>A p.M1154I | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs776322064, COSV58457469; called by muse, mutect2, varscan2
- NIPBL | c.728C>G p.S243* | Nonsense Mutation (SNP) | VAF 22/416 reads (5%) | catalogued as COSV56953800; called by muse, mutect2
- NLRP5 | c.137C>G p.S46C | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as COSV101173844; called by muse, mutect2, varscan2
- NR1I2 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 107/458 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.057); catalogued as rs781353779; called by muse, mutect2, varscan2
- OR51E1 | c.286C>A p.Q96K | Missense Mutation (SNP) | VAF 39/295 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.205); catalogued as rs1211432093, COSV101211574; called by muse, mutect2, varscan2
- PAWR | c.740G>A p.S247N | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.215); catalogued as rs1315510293, COSV100174015; called by muse, mutect2
- PCDH15 | c.874C>G p.P292A | Missense Mutation (SNP) | VAF 54/409 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.9); catalogued as COSV57276028; called by muse, mutect2, varscan2
- PCYOX1 | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs1235266883; called by muse, mutect2
- PDCL2 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as COSV55263078, COSV99824137; called by muse, mutect2, varscan2
- PDE3A | c.2607C>A p.H869Q | Missense Mutation (SNP) | VAF 54/524 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100762368; called by muse, mutect2
- PDE3A | c.2608G>C p.A870P | Missense Mutation (SNP) | VAF 54/533 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100762238, COSV100762421; called by muse, mutect2
- PDHA2 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 82/592 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs375558920; called by muse, varscan2
- PIAS3 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 78/274 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as rs587640377; called by muse, varscan2
- PIK3CB | c.899T>C p.I300T | Missense Mutation (SNP) | VAF 58/257 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV56686366; called by muse, mutect2, varscan2
- PLCXD3 | c.841C>A p.R281S | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV60607794; called by muse, mutect2, varscan2
- PLCXD3 | c.286G>C p.D96H | Missense Mutation (SNP) | VAF 46/160 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774656951, COSV100126287; called by muse, varscan2
- PRAG1 | c.1962G>A p.W654* | Nonsense Mutation (SNP) | VAF 47/174 reads (27%) | catalogued as COSV100422111; called by muse, mutect2, varscan2
- PRDM10 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 79/281 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV58802138; called by muse, mutect2, varscan2
- PTEN | c.129A>C p.E43D | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV64296386; called by muse, mutect2
- PTGIS | c.1010G>A p.S337N | Missense Mutation (SNP) | VAF 17/219 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV99720715; called by muse, mutect2
- PTK6 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.346); catalogued as COSV53917238; called by muse, mutect2, varscan2
- PTPRN | c.1393C>T p.R465C | Missense Mutation (SNP) | VAF 85/255 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs760369284, COSV99834502; called by muse, mutect2, varscan2
- PWWP3B | c.1579G>C p.A527P | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV61800029; called by muse, mutect2, varscan2
- PZP | c.371C>T p.T124I | Missense Mutation (SNP) | VAF 100/579 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1359656480; called by muse, mutect2, varscan2
- RBFOX2 | c.1325G>A p.R442Q (on ENST00000438146 / NM_001349995.2; = p.E355K on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1038642382; called by muse, mutect2, varscan2
- RUNX1T1 | c.1031G>A p.R344K (on ENST00000265814 / NM_001198628.1; = p.R317K on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/476 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.566); catalogued as rs761010745, COSV56161087; called by muse, varscan2
- RUVBL2 | c.66C>T p.I22= | Splice Region (SNP) | VAF 20/300 reads (7%) | catalogued as rs866373782, COSV55484964; called by muse, mutect2
- RYR2 | c.7315G>T p.A2439S | Missense Mutation (SNP) | VAF 42/347 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as CM1414692; called by muse, mutect2, varscan2
- SI | c.3087G>T p.M1029I | Missense Mutation (SNP) | VAF 22/299 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.88); catalogued as COSV100016786; called by muse, mutect2
- SIPA1L3 | c.5338G>T p.E1780* | Nonsense Mutation (SNP) | VAF 25/141 reads (18%) | catalogued as rs868607224; called by muse, mutect2, varscan2
- SLC17A6 | c.31C>A p.P11T | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV54136424; called by muse, mutect2, varscan2
- SLC2A1 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 42/650 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99055596; called by muse, mutect2
- SLC6A5 | c.1621C>G p.Q541E | Missense Mutation (SNP) | VAF 60/602 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0.013); catalogued as rs931802079; called by muse, mutect2, varscan2
- SLCO1C1 | c.1790G>C p.R597T | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99859229; called by muse, mutect2
- SNAPC4 | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1162283454, COSV53734758; called by muse, mutect2
- SPANXN3 | c.350C>A p.S117* | Nonsense Mutation (SNP) | VAF 44/112 reads (39%) | catalogued as rs781802757, COSV100980884, COSV65139992; called by muse, mutect2, varscan2
- SPHKAP | c.3662C>A p.A1221D | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0.039); catalogued as COSV60897923; called by muse, mutect2, varscan2
- TAF4 | c.608C>G p.A203G | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.118); catalogued as rs1214704984, COSV53339106; called by muse, mutect2, varscan2
- TBX20 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 244/1161 reads (21%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.915); catalogued as rs778902854, COSV68783375; called by muse, mutect2, varscan2
- TBX22 | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 120/252 reads (48%) | catalogued as COSV64787255; called by muse, mutect2, varscan2
- TESMIN | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 54/890 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs775340621, COSV54832149; called by muse, mutect2
- TESPA1 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs776869070, COSV57260847; called by muse, mutect2, varscan2
- TEX13C | c.1452G>T p.Q484H | Missense Mutation (SNP) | VAF 34/287 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as rs1395160113; called by muse, mutect2, varscan2
- TEX14 | c.1276G>C p.E426Q (on ENST00000240361 / NM_001201457.2; = p.E420Q on NM_031272.5) | Missense Mutation (SNP) | VAF 138/538 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1482210026; called by muse, mutect2, varscan2
- TLL1 | c.220C>G p.Q74E | Missense Mutation (SNP) | VAF 18/259 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.024); catalogued as COSV50314546, COSV99288843; called by muse, mutect2
- TMEM132B | c.1405G>A p.D469N | Missense Mutation (SNP) | VAF 53/493 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as rs199976507, COSV54744376; called by muse, mutect2, varscan2
- TMEM240 | c.9G>A p.M3I | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.607); catalogued as rs1164149082; called by muse, mutect2, varscan2
- TRIM43 | c.691C>G p.Q231E | Missense Mutation (SNP) | VAF 55/241 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1187522553; called by muse, mutect2, varscan2
- TRPA1 | c.2366C>T p.A789V | Missense Mutation (SNP) | VAF 53/280 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1193285296, COSV51565866; called by muse, mutect2, varscan2
- TRPV5 | c.86G>C p.W29S | Missense Mutation (SNP) | VAF 39/259 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV54688870; called by muse, mutect2, varscan2
- TSPEAR | c.955C>G p.Q319E | Missense Mutation (SNP) | VAF 100/281 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs782359643; called by muse, mutect2, varscan2
- TTC7B | c.2030C>A p.S677* | Nonsense Mutation (SNP) | VAF 35/146 reads (24%) | catalogued as COSV60628167; called by muse, mutect2, varscan2
- TTN | c.51637G>C p.E17213Q (on ENST00000591111; = p.E9789Q on NM_003319.4) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | PolyPhen possibly damaging (0.801); catalogued as COSV59933833; called by muse, mutect2
- UGT3A1 | c.1226C>T p.S409F | Missense Mutation (SNP) | VAF 38/614 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.133); catalogued as COSV57102041; called by muse, mutect2
- WAC | c.1865G>A p.R622Q | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs759496172, COSV61568766, COSV61569330; called by muse, mutect2, varscan2
- WDR97 | c.4691C>T p.A1564V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.003); catalogued as rs979737780; called by muse, mutect2, varscan2
- WNK2 | c.3891C>A p.N1297K | Missense Mutation (SNP) | VAF 62/369 reads (17%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.855); catalogued as COSV99035231; called by muse, mutect2, varscan2
- YOD1 | c.438G>T p.L146F | Missense Mutation (SNP) | VAF 44/312 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as rs750860045, COSV60006590; called by muse, mutect2, varscan2
- ZNF135 | c.701G>A p.R234Q (on ENST00000313434 / NM_001289401.2; = p.R246Q on NM_003436.4) | Missense Mutation (SNP) | VAF 165/628 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as rs202150919, COSV57881522; called by muse, mutect2, varscan2
- ZNF257 | c.1609C>G p.H537D | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV71312776; called by muse, mutect2, varscan2
- ZNF548 | c.1027G>A p.G343R | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV60241063; called by muse, mutect2, varscan2
- ZNF630 | c.122A>G p.Y41C | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as rs782487217; called by muse, mutect2, varscan2
- ZNF800 | c.1937A>G p.N646S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs561952635; called by muse, mutect2, varscan2
- ZNF823 | c.1177T>C p.C393R (on ENST00000341191 / NM_001297610.2; = p.C349R on NM_017507.2) | Missense Mutation (SNP) | VAF 76/419 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201226152; called by muse, mutect2, varscan2
- ZNF90 | c.966C>G p.F322L | Missense Mutation (SNP) | VAF 57/514 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV69004646; called by muse, mutect2, varscan2
- ACIN1 | c.3646del p.R1216Efs*14 | Frame Shift Del (DEL) | VAF 63/648 reads (10%) | called by mutect2, pindel, varscan2
- ACP3 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADAMTS19 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- AGBL2 | c.700A>G p.I234V | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHR | c.93C>G p.I31M | Missense Mutation (SNP) | VAF 7/163 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); called by muse, mutect2
- AHSG | c.186G>C p.Q62H | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- AKAP6 | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 83/554 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- AKAP6 | c.5689G>T p.G1897C | Missense Mutation (SNP) | VAF 70/208 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ANAPC1P2 | n.182G>T | Splice Region (SNP) | VAF 22/212 reads (10%) | called by mutect2, varscan2
- ANK1 | c.74T>G p.L25W | Missense Mutation (SNP) | VAF 106/799 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANO3 | c.1746C>G p.F582L | Missense Mutation (SNP) | VAF 15/273 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.044); called by muse, mutect2
- ANXA5 | c.692G>T p.G231V | Missense Mutation (SNP) | VAF 42/275 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APOB | c.7082T>G p.L2361* | Nonsense Mutation (SNP) | VAF 24/243 reads (10%) | called by muse, mutect2, varscan2
- ARNT2 | c.1637G>T p.G546V | Missense Mutation (SNP) | VAF 53/272 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ASIC2 | c.865T>A p.C289S | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASXL3 | c.6660G>C p.M2220I | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BRIP1 | c.132G>T p.L44F | Missense Mutation (SNP) | VAF 83/561 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C11orf42 | c.790del p.Q264Rfs*92 | Frame Shift Del (DEL) | VAF 38/170 reads (22%) | called by mutect2, pindel, varscan2
- C17orf67 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 25/278 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- C4orf54 | c.2851G>C p.E951Q | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- C8orf34 | c.475+1G>A p.X159_splice | Splice Site (SNP) | VAF 24/153 reads (16%) | called by muse, varscan2
- CACNA1B | c.3970G>T p.G1324C | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CAPN6 | c.465G>A p.M155I | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CCDC166 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CCDC88C | c.4622G>C p.R1541P | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); called by muse, mutect2
- CCT2 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 69/551 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CD1E | c.1145C>A p.T382K | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- CDH18 | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- CDH20 | c.2071G>T p.A691S | Missense Mutation (SNP) | VAF 128/234 reads (55%) | SIFT tolerated (0.63); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CELSR3 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- CEP164 | c.2113T>C p.S705P | Missense Mutation (SNP) | VAF 115/350 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CLEC16A | c.1771G>T p.G591C | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- CLEC6A | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 150/408 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CLPB | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 49/280 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTNAP2 | c.802G>A p.G268R | Missense Mutation (SNP) | VAF 26/402 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CPNE1 | c.107_110del p.V36Efs*45 (on ENST00000352393; = p.V41Efs*45 on NM_003915.5) | Frame Shift Del (DEL) | VAF 8/53 reads (15%) | called by pindel, varscan2
- CPNE1 | c.98T>C p.L33S (on ENST00000352393; = p.L38S on NM_003915.5) | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, varscan2
- CRAMP1 | c.2286_2296del p.E762Dfs*60 | Frame Shift Del (DEL) | VAF 45/341 reads (13%) | called by mutect2, pindel
- CSMD3 | c.6233G>C p.C2078S (on ENST00000297405 / NM_001363185.1; = p.C1974S on NM_052900.3) | Missense Mutation (SNP) | VAF 60/485 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSMD3 | c.4013C>A p.T1338K (on ENST00000297405 / NM_001363185.1; = p.T1234K on NM_052900.3) | Missense Mutation (SNP) | VAF 24/432 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.268); called by muse, mutect2
- CTNND2 | c.499C>G p.Q167E | Missense Mutation (SNP) | VAF 54/361 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- CUTC | c.204A>C p.Q68H | Missense Mutation (SNP) | VAF 84/252 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- DCDC1 | c.4418T>C p.L1473P (on ENST00000597505 / NM_001367979.1; = p.L580P on NM_020869.3) | Missense Mutation (SNP) | VAF 48/187 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- DDX4 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 52/343 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DENND5B | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.041); called by muse, mutect2
- DENND6B | c.1138+3C>T | Splice Region (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- DLC1 | c.3601C>G p.L1201V (on ENST00000276297 / NM_001348081.2; = p.L764V on NM_006094.5) | Missense Mutation (SNP) | VAF 102/448 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- DLGAP1 | c.2370C>A p.H790Q | Missense Mutation (SNP) | VAF 126/544 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by mutect2, varscan2
- DLGAP2 | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 51/287 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- DNAH7 | c.8392A>G p.I2798V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- DNAH9 | c.12916T>A p.W4306R | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DTNA | c.1592G>C p.R531T | Missense Mutation (SNP) | VAF 24/632 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- DUSP2 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 55/81 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DUT | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.017); called by muse, mutect2
- EEF1G | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 59/494 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- EPC2 | c.1825C>T p.H609Y | Missense Mutation (SNP) | VAF 132/377 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.163); called by muse, varscan2
- EPG5 | c.3067C>A p.L1023I | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- EPRS1 | c.3077A>T p.D1026V | Missense Mutation (SNP) | VAF 90/430 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- ESPNL | c.2704_2705del p.K902Gfs*60 | Frame Shift Del (DEL) | VAF 20/120 reads (17%) | called by mutect2, pindel, varscan2
- EYS | c.2692T>C p.S898P | Missense Mutation (SNP) | VAF 14/237 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- F13B | c.1243T>C p.Y415H | Missense Mutation (SNP) | VAF 19/388 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM135B | c.3500C>A p.P1167H | Missense Mutation (SNP) | VAF 43/235 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM135B | c.3117del p.T1040Pfs*67 | Frame Shift Del (DEL) | VAF 24/89 reads (27%) | called by mutect2, pindel, varscan2
- FAM205A | c.2497G>C p.E833Q | Missense Mutation (SNP) | VAF 129/758 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FAM90A26 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 46/338 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAN1 | c.2203G>A p.D735N | Missense Mutation (SNP) | VAF 11/219 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- GC | c.307C>A p.P103T | Missense Mutation (SNP) | VAF 63/601 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- GEMIN8 | c.461G>C p.R154T | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2
- GHR | c.186G>C p.E62D | Missense Mutation (SNP) | VAF 52/701 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- GNL1 | c.1100-3C>T | Splice Region (SNP) | VAF 22/398 reads (6%) | called by muse, mutect2
- GPATCH8 | c.2594C>T p.S865F | Missense Mutation (SNP) | VAF 53/265 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- GPATCH8 | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); called by muse, mutect2, varscan2
- GPR55 | c.468C>G p.I156M | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- GPR6 | c.689T>A p.L230H | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRM7 | c.39G>C p.L13F | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- HACE1 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 98/382 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IFT52 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 15/271 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2
- IGHV1OR15-9 | c.228C>A p.S76R | Missense Mutation (SNP) | VAF 83/498 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IL16 | c.2557C>T p.Q853* (on ENST00000302987 / NM_172217.5; = p.Q152* on NM_004513.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/224 reads (7%) | called by muse, mutect2
- INSM1 | c.948G>T p.W316C | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IQGAP2 | c.3846G>C p.L1282F | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ISCU | c.495G>C p.E165D (on ENST00000311893 / NM_213595.4; = p.E140D on NM_014301.4) | Missense Mutation (SNP) | VAF 81/646 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- JRK | c.1690A>G p.T564A | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, varscan2
- KCNAB3 | c.948C>A p.D316E | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNG4 | c.200del p.G67Afs*16 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- KIAA1210 | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- KLHL12 | c.726C>G p.I242M | Missense Mutation (SNP) | VAF 32/249 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- KLHL31 | c.1581_1582del p.E528Afs*128 | Frame Shift Del (DEL) | VAF 75/312 reads (24%) | called by mutect2, pindel, varscan2
- KLHL4 | c.877G>T p.A293S | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- KRBOX1 | c.330A>T p.R110S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT7 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 17/221 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- KRTAP10-4 | c.315C>A p.C105* | Nonsense Mutation (SNP) | VAF 47/510 reads (9%) | called by muse, mutect2, varscan2
- LAMA5 | c.423G>T p.E141D | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, varscan2
- LIPN | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- LRGUK | c.2326G>C p.E776Q | Missense Mutation (SNP) | VAF 19/204 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- MAPRE1 | c.805T>C p.*269Qext*56 | Nonstop Mutation (SNP) | VAF 55/186 reads (30%) | called by muse, mutect2, varscan2
- MARK1 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 44/219 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MASTL | c.2092A>C p.T698P | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.277); called by muse, mutect2
- MAT2B | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- METTL25 | c.361G>C p.G121R | Missense Mutation (SNP) | VAF 66/286 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- MIA2 | c.151A>T p.R51* | Nonsense Mutation (SNP) | VAF 19/392 reads (5%) | called by muse, mutect2
- MIEN1 | c.47A>T p.E16V | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- MKRN3 | c.1354G>T p.G452* | Nonsense Mutation (SNP) | VAF 71/358 reads (20%) | called by muse, mutect2, varscan2
- MOSMO | c.152G>T p.G51V | Missense Mutation (SNP) | VAF 129/530 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MUC4 | c.12311C>T p.S4104L | Missense Mutation (SNP) | VAF 46/681 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.78); called by muse, mutect2
- MVB12B | c.458G>C p.R153P | Missense Mutation (SNP) | VAF 41/363 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MYLK2 | c.934G>T p.A312S | Missense Mutation (SNP) | VAF 104/548 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAALADL2 | c.1414del p.A472Rfs*6 | Frame Shift Del (DEL) | VAF 166/653 reads (25%) | called by mutect2, pindel, varscan2
- NCKAP5 | c.4127C>A p.S1376Y | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- NCKAP5 | c.3746G>A p.R1249K | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NDUFAF5 | c.379A>T p.N127Y | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2
- NEDD8 | c.217C>G p.L73V | Missense Mutation (SNP) | VAF 161/518 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, varscan2
- NELL1 | c.1646-1G>C p.X549_splice | Splice Site (SNP) | VAF 36/227 reads (16%) | called by muse, mutect2, varscan2
- NEU4 | c.119T>C p.V40A (on ENST00000391969 / NM_001167602.3; = p.V52A on NM_080741.4) | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NEUROD6 | c.718T>A p.Y240N | Missense Mutation (SNP) | VAF 163/636 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NIPBL | c.4027C>G p.H1343D | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2
- OBSCN | c.8339C>A p.S2780Y | Missense Mutation (SNP) | VAF 77/447 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- OPRPN | c.497G>T p.S166I | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR2L2 | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 35/359 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- OTOGL | c.2645C>T p.S882F (on ENST00000547103; = p.S873F on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/324 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- OXR1 | c.944G>C p.R315T (on ENST00000442977 / NM_001198532.1; = p.R314T on NM_018002.3) | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- P3H2 | c.32T>G p.L11R | Missense Mutation (SNP) | VAF 112/300 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PABPC5 | c.1072G>T p.V358L | Missense Mutation (SNP) | VAF 102/217 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PALB2 | c.3347G>T p.G1116V | Missense Mutation (SNP) | VAF 151/683 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1632T>G p.F544L (on ENST00000259318 / NM_001136562.3; = p.F775L on NM_007203.5) | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAPSS2 | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 130/366 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- PAX5 | c.213-2A>C p.X71_splice | Splice Site (SNP) | VAF 32/243 reads (13%) | called by muse, mutect2, varscan2
- PCMTD1 | c.707-1G>T p.X236_splice | Splice Site (SNP) | VAF 18/124 reads (15%) | called by muse, mutect2
- PCSK5 | c.2167C>T p.H723Y | Missense Mutation (SNP) | VAF 12/188 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.056); called by muse, mutect2
- PDIA3 | c.1067A>G p.Y356C | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PDS5A | c.3053C>T p.S1018L | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.015); called by muse, mutect2
- PHLDB2 | c.2176G>T p.E726* (on ENST00000393925 / NM_001134439.2; = p.E683* on NM_145753.2) | Nonsense Mutation (SNP) | VAF 16/293 reads (5%) | called by muse, mutect2
- PHRF1 | c.144C>A p.S48R | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- PIGO | c.2842C>A p.L948I | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PIK3C2A | c.1768G>A p.G590S | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0.015); called by muse, mutect2
- PIN4 | c.330G>A p.M110I (on ENST00000664196; = p.M85I on NM_006223.4) | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PKN1 | c.1690C>T p.Q564* | Nonsense Mutation (SNP) | VAF 32/353 reads (9%) | called by muse, mutect2
- PKP4 | c.3087G>T p.L1029F | Missense Mutation (SNP) | VAF 165/429 reads (38%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLD1 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 119/287 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.147); called by muse, varscan2
- PNLIPRP1 | c.1213G>C p.D405H | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PNLIPRP3 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 69/306 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.18); called by muse, varscan2
- POLR2H | c.278A>G p.Y93C | Missense Mutation (SNP) | VAF 93/486 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- PPP1R3C | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 38/554 reads (7%) | called by muse, mutect2
- PPP4R3C | c.2148G>T p.M716I | Missense Mutation (SNP) | VAF 49/214 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PRAG1 | c.2203A>T p.K735* | Nonsense Mutation (SNP) | VAF 47/310 reads (15%) | called by muse, mutect2, varscan2
- RELN | c.5884G>C p.D1962H | Missense Mutation (SNP) | VAF 92/370 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RELN | c.4516G>T p.V1506F | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- REPIN1 | c.1511C>T p.S504L | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.666); called by muse, mutect2
- RETREG3 | c.60G>T p.R20S | Missense Mutation (SNP) | VAF 69/317 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- RP1 | c.4487A>G p.E1496G | Missense Mutation (SNP) | VAF 56/242 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RPN1 | c.710C>G p.S237C | Missense Mutation (SNP) | VAF 64/614 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR3 | c.12262T>A p.C4088S (on ENST00000389232; = p.C4089S on NM_001036.6) | Missense Mutation (SNP) | VAF 56/408 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- S1PR5 | c.1080C>A p.F360L | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SAMD3 | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 37/133 reads (28%) | called by muse, mutect2, varscan2
- SEMA4C | c.1124A>G p.H375R | Missense Mutation (SNP) | VAF 66/152 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SFMBT2 | c.6G>C p.E2D | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.956); called by muse, mutect2
- SGK3 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 17/310 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.052); called by muse, mutect2
- SHANK2 | c.4629A>T p.K1543N | Missense Mutation (SNP) | VAF 64/2138 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); called by muse, mutect2
- SHC4 | c.1614C>A p.S538R | Missense Mutation (SNP) | VAF 44/589 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2
- SHISA7 | c.254A>T p.Y85F | Missense Mutation (SNP) | VAF 86/248 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SI | c.493C>G p.P165A | Missense Mutation (SNP) | VAF 85/318 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SIPA1L3 | c.1444C>T p.Q482* | Nonsense Mutation (SNP) | VAF 143/427 reads (33%) | called by muse, mutect2, varscan2
- SLC30A8 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by mutect2, varscan2
- SLC5A5 | c.1448G>T p.C483F | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- SLC5A5 | c.1706G>C p.R569P | Missense Mutation (SNP) | VAF 132/562 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLC6A15 | c.913C>T p.Q305* | Nonsense Mutation (SNP) | VAF 36/350 reads (10%) | called by muse, mutect2
- SLFN14 | c.290A>T p.D97V | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLITRK1 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- SLITRK4 | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNAP25 | c.94A>T p.M32L | Missense Mutation (SNP) | VAF 98/558 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- SORCS3 | c.562T>A p.F188I | Missense Mutation (SNP) | VAF 89/192 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- SPANXB1 | c.279C>G p.F93L | Missense Mutation (SNP) | VAF 36/1315 reads (3%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2
- SPATA31A3 | c.2740C>T p.P914S | Missense Mutation (SNP) | VAF 34/200 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by mutect2, varscan2
- SPINK5 | c.291T>G p.C97W | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ST8SIA3 | c.943G>T p.E315* | Nonsense Mutation (SNP) | VAF 14/339 reads (4%) | called by muse, mutect2
- SYCE1L | c.340A>G p.K114E | Missense Mutation (SNP) | VAF 72/338 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- TAS2R39 | c.865A>T p.N289Y | Missense Mutation (SNP) | VAF 114/346 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TEX51 | c.365-2A>C p.X122_splice | Splice Site (SNP) | VAF 100/278 reads (36%) | called by muse, mutect2, varscan2
- TFAP2D | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 84/274 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TGM4 | c.860G>T p.R287L | Missense Mutation (SNP) | VAF 43/173 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THSD7B | c.4616A>T p.H1539L (on ENST00000272643; = p.H1537L on NM_001316349.2) | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.599); called by muse, varscan2
- TMEM132E | c.326A>C p.Q109P | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- TMIGD3 | c.565C>G p.L189V (on ENST00000369717 / NM_001081976.2; = p.L270V on NM_020683.7) | Missense Mutation (SNP) | VAF 66/366 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- TNPO2 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TPRX1 | c.1094G>A p.G365E | Missense Mutation (SNP) | VAF 52/319 reads (16%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- TRAV7 | c.192del p.K66Nfs*18 | Frame Shift Del (DEL) | VAF 136/512 reads (27%) | called by pindel, varscan2
- TRIM64C | c.412+1G>C p.X138_splice | Splice Site (SNP) | VAF 48/240 reads (20%) | called by muse, mutect2, varscan2
- TRMT2B | c.798C>G p.F266L | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- TSHZ2 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.104); called by muse, mutect2
- TTN | c.50962G>C p.E16988Q (on ENST00000591111; = p.E9564Q on NM_003319.4) | Missense Mutation (SNP) | VAF 10/124 reads (8%) | PolyPhen probably damaging (0.997); called by muse, mutect2
- UGGT2 | c.1685A>G p.Q562R | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- UNC5C | c.2509A>T p.T837S | Missense Mutation (SNP) | VAF 27/247 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- USH2A | c.15281C>A p.P5094Q | Missense Mutation (SNP) | VAF 76/368 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- USH2A | c.4140C>G p.I1380M | Missense Mutation (SNP) | VAF 81/416 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- VPS13D | c.6284A>T p.E2095V | Missense Mutation (SNP) | VAF 42/520 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- VPS8 | c.2618C>T p.S873F (on ENST00000625842 / NM_001349294.1; = p.S871F on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/496 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.355); called by muse, mutect2
- VWC2 | c.691T>C p.F231L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- WWC2 | c.3091T>A p.S1031T | Missense Mutation (SNP) | VAF 23/374 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.644); called by muse, mutect2
- XIRP1 | c.277T>A p.C93S | Missense Mutation (SNP) | VAF 99/402 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ZBTB7C | c.1445A>G p.K482R | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZDBF2 | c.1714G>A p.D572N | Missense Mutation (SNP) | VAF 35/223 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZMYM2 | c.3158G>T p.G1053V | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ZNF146 | c.872C>G p.T291S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); called by muse, varscan2
- ZNF483 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 26/393 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- ZNF483 | c.1615A>T p.I539F | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- ZNF660 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 19/280 reads (7%) | called by muse, mutect2
- ZNF785 | c.31C>G p.H11D | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCD1 | c.1386G>A p.K462= | Silent (SNP) | VAF 24/114 reads (21%) | called by muse, mutect2, varscan2
- ACVR1B | c.654T>C p.F218= | Silent (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- ADAD2 | c.1386C>T p.T462= (on ENST00000315906 / NM_001145400.2; = p.T544= on NM_139174.4) | Silent (SNP) | VAF 21/266 reads (8%) | catalogued as rs758562581; called by muse, mutect2
- ADAMTS1 | c.1389G>A p.L463= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV53173812; called by muse, mutect2, varscan2
- ADCY8 | c.2712G>T p.L904= | Silent (SNP) | VAF 75/430 reads (17%) | called by muse, mutect2, varscan2
- AGPAT2 | c.186C>T p.I62= | Silent (SNP) | VAF 28/222 reads (13%) | catalogued as rs1217651546; called by muse, mutect2, varscan2
- AL645922.1 | c.1863C>T p.P621= | Silent (SNP) | VAF 69/364 reads (19%) | called by muse, mutect2, varscan2
- ARHGAP6 | c.1419G>C p.L473= | Silent (SNP) | VAF 11/116 reads (9%) | called by muse, mutect2, varscan2
- ASPM | c.420A>T p.A140= | Silent (SNP) | VAF 53/279 reads (19%) | called by muse, mutect2, varscan2
- ASTN1 | c.1095T>C p.P365= | Silent (SNP) | VAF 45/182 reads (25%) | called by muse, mutect2, varscan2
- ATG13 | c.1380G>A p.P460= (on ENST00000359513 / NM_001346321.1; = p.P423= on NM_014741.4 and 9 other RefSeq transcripts) | Silent (SNP) | VAF 41/264 reads (16%) | catalogued as rs138352791; called by muse, mutect2, varscan2
- ATP1A4 | c.2892C>A p.I964= | Silent (SNP) | VAF 101/398 reads (25%) | catalogued as rs1384275512, COSV63626161; called by muse, mutect2, varscan2
- BIRC6 | c.1077A>G p.K359= | Silent (SNP) | VAF 103/347 reads (30%) | called by muse, mutect2, varscan2
- BUB1 | c.2406C>T p.Y802= | Silent (SNP) | VAF 102/273 reads (37%) | catalogued as rs371721678; called by muse, mutect2, varscan2
- C4orf54 | c.2322C>T p.G774= | Silent (SNP) | VAF 23/95 reads (24%) | called by muse, mutect2, varscan2
- CAPN7 | c.1197A>T p.A399= | Silent (SNP) | VAF 40/366 reads (11%) | called by muse, mutect2, varscan2
- CHRD | c.570G>T p.S190= | Silent (SNP) | VAF 98/434 reads (23%) | called by muse, mutect2, varscan2
- CHRD | c.2037G>T p.P679= | Silent (SNP) | VAF 24/100 reads (24%) | called by muse, mutect2, varscan2
- CLDN18 | c.63C>T p.C21= | Silent (SNP) | VAF 85/408 reads (21%) | called by muse, mutect2, varscan2
- CLEC14A | c.600C>T p.S200= | Silent (SNP) | VAF 27/452 reads (6%) | catalogued as COSV60562867; called by muse, mutect2
- CLEC14A | c.393G>A p.V131= | Silent (SNP) | VAF 79/273 reads (29%) | called by muse, mutect2, varscan2
- COL6A3 | c.3501C>A p.I1167= | Silent (SNP) | VAF 54/316 reads (17%) | catalogued as COSV55112672; called by muse, mutect2, varscan2
- CRACR2B | c.51G>A p.G17= | Silent (SNP) | VAF 29/99 reads (29%) | catalogued as rs1224057344, COSV100351911; called by muse, mutect2, varscan2
- CRYBG3 | c.7983G>C p.G2661= | Silent (SNP) | VAF 20/168 reads (12%) | called by muse, varscan2
- CYP11B2 | c.1452C>G p.V484= | Silent (SNP) | VAF 25/417 reads (6%) | catalogued as COSV59998438; called by muse, mutect2
- DAPK1 | c.201C>A p.I67= | Silent (SNP) | VAF 59/374 reads (16%) | called by muse, mutect2, varscan2
- DCAF6 | c.474C>G p.L158= | Silent (SNP) | VAF 14/277 reads (5%) | catalogued as rs749224117; called by muse, mutect2
- DDX19A | c.915C>T p.T305= | Silent (SNP) | VAF 42/588 reads (7%) | catalogued as COSV100156426; called by muse, mutect2
- DEGS1 | c.54G>T p.P18= | Silent (SNP) | VAF 42/133 reads (32%) | called by muse, mutect2, varscan2
- DNHD1 | c.7767C>T p.F2589= | Silent (SNP) | VAF 28/171 reads (16%) | called by muse, mutect2, varscan2
- ENTPD1 | c.1461C>T p.V487= | Silent (SNP) | VAF 219/778 reads (28%) | catalogued as COSV64604864; called by muse, mutect2, varscan2
- EPHA7 | c.2784T>G p.V928= | Silent (SNP) | VAF 57/312 reads (18%) | called by muse, mutect2, varscan2
- FAM53A | c.618G>T p.P206= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs773123874; called by muse, mutect2, varscan2
- FCER1G | c.30C>A p.L10= | Silent (SNP) | VAF 41/401 reads (10%) | called by muse, mutect2
- FCGBP | c.1044C>T p.V348= | Silent (SNP) | VAF 17/199 reads (9%) | called by muse, mutect2
- FCGBP | c.849C>T p.I283= | Silent (SNP) | VAF 64/764 reads (8%) | called by muse, mutect2
- FCGBP | c.519G>T p.T173= | Silent (SNP) | VAF 96/1054 reads (9%) | called by muse, mutect2
- FOXR2 | c.135C>A p.I45= | Silent (SNP) | VAF 92/246 reads (37%) | catalogued as COSV59259950; called by muse, mutect2, varscan2
- FRY | c.7500G>A p.E2500= | Silent (SNP) | VAF 18/398 reads (5%) | called by muse, mutect2
- GBA2 | c.2616C>T p.F872= | Silent (SNP) | VAF 20/612 reads (3%) | catalogued as rs1250765787; called by muse, mutect2
- GLB1L3 | c.1932T>C p.D644= | Silent (SNP) | VAF 80/328 reads (24%) | catalogued as rs557598030, COSV101345124; called by muse, varscan2
- GPR161 | c.1485G>T p.P495= | Silent (SNP) | VAF 64/288 reads (22%) | catalogued as rs767061233, COSV54788355; called by muse, mutect2, varscan2
- GZMM | c.156G>C p.G52= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs768715164; called by muse, mutect2, varscan2
- HECTD1 | c.6102T>C p.D2034= | Silent (SNP) | VAF 21/236 reads (9%) | called by muse, mutect2
- HMCN2 | c.4422C>T p.D1474= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs1398392029; called by muse, mutect2, varscan2
- IL17RC | c.1953C>G p.L651= (on ENST00000295981 / NM_153461.4; = p.L565= on NM_032732.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2, varscan2
- IL1RAPL2 | c.1512G>C p.V504= | Silent (SNP) | VAF 35/132 reads (27%) | catalogued as COSV61152097; called by muse, mutect2, varscan2
- INSRR | c.3054G>T p.L1018= | Silent (SNP) | VAF 58/226 reads (26%) | called by muse, mutect2, varscan2
- IRX5 | c.570G>A p.E190= | Silent (SNP) | VAF 86/241 reads (36%) | catalogued as rs1365980507; called by muse, mutect2, varscan2
- KIF21B | c.4236G>A p.E1412= (on ENST00000422435 / NM_001252100.2; = p.E1399= on NM_017596.4) | Silent (SNP) | VAF 65/257 reads (25%) | called by muse, mutect2, varscan2
- KNTC1 | c.1188A>G p.P396= | Silent (SNP) | VAF 11/99 reads (11%) | called by muse, mutect2, varscan2
- LAMA3 | c.4776C>T p.F1592= | Silent (SNP) | VAF 44/852 reads (5%) | catalogued as COSV52535893; called by muse, mutect2
- LCLAT1 | c.286T>C p.L96= | Silent (SNP) | VAF 58/207 reads (28%) | catalogued as rs370802715; called by muse, mutect2, varscan2
- LRP2 | c.12762T>C p.I4254= | Silent (SNP) | VAF 113/335 reads (34%) | called by muse, mutect2, varscan2
- LRRN4 | c.2193T>C p.D731= | Silent (SNP) | VAF 63/323 reads (20%) | called by muse, mutect2, varscan2
- MAGEC3 | c.723G>A p.L241= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as COSV53580599; called by muse, mutect2, varscan2
- MAN2A1 | c.2142A>C p.G714= | Silent (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- MAP6 | c.1941G>A p.P647= | Silent (SNP) | VAF 14/234 reads (6%) | catalogued as rs755307410, COSV59076078; called by muse, mutect2
- MDGA2 | c.1899G>C p.L633= (on ENST00000399232 / NM_001113498.2; = p.L335= on NM_182830.4) | Silent (SNP) | VAF 42/507 reads (8%) | called by muse, mutect2
- MOSMO | c.153A>T p.G51= | Silent (SNP) | VAF 132/534 reads (25%) | catalogued as COSV100458771; called by muse, mutect2, varscan2
- MPST | c.213C>T p.P71= (on ENST00000341116 / NM_001369904.2; = p.P91= on NM_021126.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/65 reads (57%) | called by muse, mutect2, varscan2
- MYADM | c.12G>T p.T4= | Silent (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- NCOA3 | c.639C>A p.A213= | Silent (SNP) | VAF 29/274 reads (11%) | called by muse, mutect2, varscan2
- NDC80 | c.1782G>T p.G594= | Silent (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- NDN | c.627C>A p.A209= | Silent (SNP) | VAF 36/125 reads (29%) | catalogued as COSV59358550; called by muse, mutect2, varscan2
- NDUFAF5 | c.165G>A p.Q55= | Silent (SNP) | VAF 110/434 reads (25%) | called by muse, mutect2, varscan2
- NEMF | c.705T>C p.Y235= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs1226631650; called by muse, varscan2
- NEO1 | c.87G>A p.P29= | Silent (SNP) | VAF 35/94 reads (37%) | catalogued as rs1351839200; called by muse, mutect2, varscan2
- NLRP5 | c.327G>T p.L109= | Silent (SNP) | VAF 32/260 reads (12%) | called by muse, mutect2, varscan2
- NOVA1 | c.888C>A p.G296= | Silent (SNP) | VAF 41/271 reads (15%) | catalogued as rs148779283; called by muse, mutect2, varscan2
- OLIG3 | c.759C>T p.S253= | Silent (SNP) | VAF 34/278 reads (12%) | called by muse, varscan2
- OR10D3 | c.306C>T p.F102= | Silent (SNP) | VAF 105/460 reads (23%) | called by muse, mutect2, varscan2
- OR4C12 | c.435G>T p.V145= | Silent (SNP) | VAF 63/451 reads (14%) | catalogued as COSV58859602; called by muse, mutect2, varscan2
- OR51C1P | c.651T>C p.S217= | Silent (SNP) | VAF 24/115 reads (21%) | called by muse, mutect2, varscan2
- OR5J2 | c.345G>C p.L115= | Silent (SNP) | VAF 44/214 reads (21%) | called by muse, mutect2, varscan2
- PARP14 | c.1020C>T p.L340= | Silent (SNP) | VAF 40/215 reads (19%) | called by muse, mutect2, varscan2
- PCDHA1 | c.1629G>A p.P543= | Silent (SNP) | VAF 162/528 reads (31%) | called by muse, mutect2, varscan2
- PCK1 | c.708C>T p.G236= | Silent (SNP) | VAF 31/474 reads (7%) | catalogued as rs768241848, COSV60127838; called by muse, mutect2
- PKD1L1 | c.4548C>A p.L1516= | Silent (SNP) | VAF 56/444 reads (13%) | called by muse, mutect2, varscan2
- PKD1L1 | c.4176C>T p.I1392= | Silent (SNP) | VAF 34/274 reads (12%) | catalogued as rs768997394; called by muse, mutect2, varscan2
- PKHD1L1 | c.471T>A p.T157= | Silent (SNP) | VAF 27/250 reads (11%) | called by muse, varscan2
- PKP1 | c.1518C>T p.T506= | Silent (SNP) | VAF 83/259 reads (32%) | catalogued as rs780772450; called by muse, mutect2, varscan2
- PMFBP1 | c.2124C>T p.S708= (on ENST00000537465; = p.S703= on NM_031293.3) | Silent (SNP) | VAF 53/183 reads (29%) | catalogued as rs144723690; called by muse, mutect2, varscan2
- PODN | c.1080G>A p.V360= (on ENST00000395871; = p.V312= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 38/196 reads (19%) | called by muse, mutect2, varscan2
- POLQ | c.5520C>T p.F1840= | Silent (SNP) | VAF 16/239 reads (7%) | called by muse, mutect2
- POTEH | c.60C>G p.L20= | Silent (SNP) | VAF 78/551 reads (14%) | called by muse, varscan2
- PPFIA2 | c.1317T>C p.G439= | Silent (SNP) | VAF 30/170 reads (18%) | called by muse, mutect2, varscan2
- PRDM5 | c.729C>T p.F243= | Silent (SNP) | VAF 80/490 reads (16%) | catalogued as COSV53357865; called by muse, mutect2, varscan2
- PRR36 | c.252G>A p.G84= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs1045249663; called by muse, mutect2, varscan2
- PTPA | c.453A>G p.A151= (on ENST00000337738 / NM_178001.2; = p.A116= on NM_021131.5) | Silent (SNP) | VAF 20/254 reads (8%) | called by muse, mutect2
- S1PR5 | c.345C>G p.V115= | Silent (SNP) | VAF 25/154 reads (16%) | called by muse, mutect2, varscan2
- SALL3 | c.765C>T p.P255= | Silent (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- SBK1 | c.708G>C p.V236= | Silent (SNP) | VAF 10/224 reads (4%) | called by muse, mutect2
- SESTD1 | c.2076G>T p.V692= | Silent (SNP) | VAF 46/143 reads (32%) | called by muse, mutect2, varscan2
- SHCBP1L | c.12C>A p.G4= | Silent (SNP) | VAF 64/309 reads (21%) | catalogued as rs750256670; called by muse, mutect2, varscan2
- SHISA9 | c.978C>T p.P326= | Silent (SNP) | VAF 29/344 reads (8%) | catalogued as rs1013951152, COSV69641225, COSV69645006; called by muse, mutect2
- SIAE | c.639G>A p.L213= | Silent (SNP) | VAF 26/292 reads (9%) | called by muse, mutect2
- SLC12A1 | c.1899C>A p.V633= | Silent (SNP) | VAF 47/294 reads (16%) | catalogued as rs1334098330; called by muse, mutect2, varscan2
- SLC18A1 | c.702G>T p.G234= | Silent (SNP) | VAF 112/439 reads (26%) | called by muse, mutect2, varscan2
- SLC2A1 | c.1182C>G p.L394= | Silent (SNP) | VAF 26/525 reads (5%) | catalogued as COSV65286602, COSV65286697; called by muse, mutect2
- SLC7A9 | c.315G>A p.G105= | Silent (SNP) | VAF 104/320 reads (33%) | called by muse, mutect2, varscan2
- SMCR8 | c.36A>G p.K12= | Silent (SNP) | VAF 37/80 reads (46%) | called by mutect2, varscan2
- SPDYE4 | c.264G>T p.G88= | Silent (SNP) | VAF 102/349 reads (29%) | catalogued as rs1437931084; called by muse, mutect2, varscan2
- SYNRG | c.1926A>T p.S642= | Silent (SNP) | VAF 36/271 reads (13%) | called by muse, mutect2, varscan2
- TACC2 | c.1635G>T p.G545= | Silent (SNP) | VAF 15/184 reads (8%) | called by muse, mutect2
- TMEM132B | c.387C>T p.I129= | Silent (SNP) | VAF 21/499 reads (4%) | called by muse, mutect2
- TMEM138 | c.33C>T p.L11= | Silent (SNP) | VAF 30/267 reads (11%) | called by muse, mutect2, varscan2
- TMEM225 | c.222T>A p.L74= | Silent (SNP) | VAF 38/154 reads (25%) | called by muse, mutect2, varscan2
- TMPRSS9 | c.2217C>A p.I739= (on ENST00000648592; = p.I705= on NM_182973.2) | Silent (SNP) | VAF 41/176 reads (23%) | catalogued as rs780210816, COSV53114234, COSV53114642; called by muse, mutect2, varscan2
- TOPAZ1 | c.73C>A p.R25= | Silent (SNP) | VAF 62/297 reads (21%) | called by muse, mutect2, varscan2
- TRIM72 | c.942G>A p.S314= | Silent (SNP) | VAF 20/252 reads (8%) | catalogued as rs781404405; called by muse, mutect2
- TRIM9 | c.1923C>A p.I641= | Silent (SNP) | VAF 58/158 reads (37%) | called by muse, mutect2
- TSPEAR | c.420C>T p.A140= | Silent (SNP) | VAF 111/304 reads (37%) | called by muse, mutect2, varscan2
- TTC30B | c.1704C>T p.I568= | Silent (SNP) | VAF 24/398 reads (6%) | called by muse, mutect2
- TUBB8B | c.90C>T p.I30= | Silent (SNP) | VAF 56/359 reads (16%) | catalogued as rs767990363; called by muse, mutect2, varscan2
- UGT2B28 | c.1539G>A p.L513= | Silent (SNP) | VAF 35/289 reads (12%) | called by muse, varscan2
- USH2A | c.9229C>T p.L3077= | Silent (SNP) | VAF 48/466 reads (10%) | called by muse, mutect2
- XIRP1 | c.1671G>A p.Q557= | Silent (SNP) | VAF 58/247 reads (23%) | catalogued as rs748378421; called by muse, mutect2, varscan2
- ZFP57 | c.336C>T p.N112= | Silent (SNP) | VAF 71/628 reads (11%) | called by muse, mutect2, varscan2
- ZNF483 | c.963G>A p.L321= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as COSV58515131; called by muse, mutect2, varscan2
- ZNF599 | c.111G>C p.V37= | Silent (SNP) | VAF 64/513 reads (12%) | called by muse, mutect2, varscan2
- ZNF671 | c.93T>A p.A31= | Silent (SNP) | VAF 31/206 reads (15%) | called by muse, mutect2, varscan2
- ZSWIM6 | c.2727C>A p.T909= | Silent (SNP) | VAF 25/126 reads (20%) | called by muse, mutect2, varscan2
- ABCA2 | c.251-372G>T | Intron (SNP) | VAF 48/201 reads (24%) | called by muse, mutect2, varscan2
- ABHD16A | c.-11G>T | 5'UTR (SNP) | VAF 9/15 reads (60%) | catalogued as rs1165718076; called by muse, mutect2, varscan2
- AC011525.1 | n.877G>A | RNA (SNP) | VAF 52/268 reads (19%) | catalogued as rs1315439249; called by muse, mutect2, varscan2
- AC092687.1 | n.343G>C | RNA (SNP) | VAF 12/238 reads (5%) | called by muse, mutect2
- AC109583.1 | c.-1319+362G>A | Intron (SNP) | VAF 31/119 reads (26%) | called by muse, mutect2, varscan2
- AC114741.1 | n.109G>A | RNA (SNP) | VAF 40/291 reads (14%) | called by muse, mutect2, varscan2
- AC244394.2 | n.1767C>T | RNA (SNP) | VAF 103/646 reads (16%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-8973C>A | Intron (SNP) | VAF 124/421 reads (29%) | called by muse, mutect2, varscan2
- ACAD11 | c.1774+56A>C | Intron (SNP) | VAF 23/92 reads (25%) | called by muse, mutect2, varscan2
- ACY1 | c.657+29G>C | Intron (SNP) | VAF 57/544 reads (10%) | called by muse, mutect2, varscan2
- ADAM20P1 | n.1498C>G | RNA (SNP) | VAF 54/455 reads (12%) | called by muse, varscan2
- AP000356.3 | chr22:24650657 G>A | 3'Flank (SNP) | VAF 22/56 reads (39%) | catalogued as rs1184204405; called by muse, mutect2, varscan2
- BNIP3L | c.-26G>A | 5'UTR (SNP) | VAF 97/490 reads (20%) | called by muse, varscan2
- CD8A | chr2:86791005 C>A | 5'Flank (SNP) | VAF 29/215 reads (13%) | called by muse, mutect2, varscan2
- CEP83 | c.1707+3398C>T | Intron (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2, varscan2
- COPS7A | c.162+849A>G | Intron (SNP) | VAF 105/376 reads (28%) | catalogued as rs1043348121; called by muse, mutect2, varscan2
- CTSB | c.447-210G>T | Intron (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2
- DISP1 | c.889+44G>T | Intron (SNP) | VAF 69/360 reads (19%) | catalogued as rs375229271; called by muse, mutect2, varscan2
- DOCK4 | c.1066+160C>T | Intron (SNP) | VAF 19/156 reads (12%) | called by muse, mutect2, varscan2
- DYNC1I1 | c.365+5203C>G | Intron (SNP) | VAF 51/169 reads (30%) | called by muse, mutect2, varscan2
- EBAG9 | c.522-1013C>G | Intron (SNP) | VAF 30/188 reads (16%) | catalogued as rs1300493235; called by muse, mutect2, varscan2
- EFCAB12 | chr3:129397234 C>T | 3'Flank (SNP) | VAF 23/446 reads (5%) | called by muse, mutect2
- FOXE1 | c.*41C>T | 3'UTR (SNP) | VAF 70/275 reads (25%) | called by muse, mutect2, varscan2
- GABRB3 | chr15:26773652 G>T | 5'Flank (SNP) | VAF 61/259 reads (24%) | catalogued as rs767732543; called by muse, mutect2, varscan2
- GCKR | c.969-18C>A | Intron (SNP) | VAF 53/434 reads (12%) | called by muse, mutect2, varscan2
- GFM1 | c.1083+1205G>C | Intron (SNP) | VAF 106/412 reads (26%) | called by muse, mutect2, varscan2
- GRM7 | c.-152G>T | 5'UTR (SNP) | VAF 26/247 reads (11%) | called by muse, mutect2, varscan2
- GRM7 | c.519+94700A>C | Intron (SNP) | VAF 70/310 reads (23%) | called by mutect2, varscan2
- HAX1 | c.664-27G>A | Intron (SNP) | VAF 29/528 reads (5%) | called by muse, mutect2
- HERC2P4 | n.411G>T | RNA (SNP) | VAF 48/282 reads (17%) | catalogued as rs752875944; called by muse, mutect2, varscan2
- ITGA3 | c.*1237C>G | 3'UTR (SNP) | VAF 12/69 reads (17%) | called by muse, mutect2, varscan2
- LINC01100 | n.164C>G | RNA (SNP) | VAF 72/423 reads (17%) | called by muse, mutect2, varscan2
- LINC01387 | n.384G>A | RNA (SNP) | VAF 58/382 reads (15%) | catalogued as rs1345425585; called by muse, mutect2, varscan2
- LINC02740 | n.235C>A | RNA (SNP) | VAF 18/280 reads (6%) | called by muse, mutect2
- MST1L | n.178G>C | RNA (SNP) | VAF 45/748 reads (6%) | called by muse, mutect2
- NFKBIB | c.-16_-9del | 5'UTR (DEL) | VAF 26/43 reads (60%) | called by mutect2, pindel, varscan2
- NKRF | c.-17+2262A>G | Intron (SNP) | VAF 58/168 reads (35%) | catalogued as rs868457556; called by muse, mutect2, varscan2
- NUP214 | c.6239+18dup | Intron (INS) | VAF 64/495 reads (13%) | called by mutect2, pindel, varscan2
- OR2L1P | n.560C>T | RNA (SNP) | VAF 58/529 reads (11%) | called by muse, mutect2, varscan2
- OR5H15 | c.926-20G>T | Intron (SNP) | VAF 14/168 reads (8%) | catalogued as COSV62948097; called by muse, mutect2
- OS9 | c.*22T>A | 3'UTR (SNP) | VAF 25/191 reads (13%) | catalogued as rs747210677; called by muse, mutect2, varscan2
- PKN2 | c.-45G>T | 5'UTR (SNP) | VAF 67/164 reads (41%) | called by muse, mutect2, varscan2
- PPP1R1B | chr17:39622152 G>C | 5'Flank (SNP) | VAF 56/453 reads (12%) | called by muse, mutect2, varscan2
- PRICKLE4 | c.668-39C>T | Intron (SNP) | VAF 20/260 reads (8%) | called by muse, mutect2
- RBM34 | chr1:235161335 G>C | 5'Flank (SNP) | VAF 60/148 reads (41%) | catalogued as rs752245449, COSV64012395; called by muse, mutect2, varscan2
- RFPL3 | chr22:32363046 C>G | 3'Flank (SNP) | VAF 77/198 reads (39%) | called by muse, mutect2, varscan2
- RIC8B | c.1451+10479A>C | Intron (SNP) | VAF 11/124 reads (9%) | called by muse, mutect2
- RPL3 | c.366-121C>T | Intron (SNP) | VAF 33/104 reads (32%) | called by muse, mutect2, varscan2
- SDHAP2 | n.797G>C | RNA (SNP) | VAF 149/2006 reads (7%) | called by muse, mutect2
- SEPTIN9 | c.77-28511C>T | Intron (SNP) | VAF 40/339 reads (12%) | catalogued as rs763017824; called by muse, mutect2, varscan2
- SLC22A17 | n.1760C>A | RNA (SNP) | VAF 23/292 reads (8%) | called by muse, mutect2
- SNORD108 | n.40A>G | RNA (SNP) | VAF 30/234 reads (13%) | called by muse, varscan2
- SNORD116-17 | n.86G>A | RNA (SNP) | VAF 36/498 reads (7%) | called by muse, mutect2
- SNORD116-22 | chr15:25092177 T>C | 3'Flank (SNP) | VAF 50/224 reads (22%) | called by muse, mutect2, varscan2
- SOX5 | chr12:23950872 G>A | 5'Flank (SNP) | VAF 26/256 reads (10%) | called by muse, varscan2
- SPATA31C1 | n.3632G>C | RNA (SNP) | VAF 86/552 reads (16%) | called by muse, mutect2, varscan2
- TGFBR2 | c.1255-22T>G | Intron (SNP) | VAF 71/356 reads (20%) | called by muse, mutect2, varscan2
- TMEM59L | c.664+515del | Intron (DEL) | VAF 38/182 reads (21%) | called by mutect2, pindel, varscan2
- TUBB7P | n.50G>T | RNA (SNP) | VAF 29/253 reads (11%) | called by muse, mutect2, varscan2
- UBE2DNL | n.119A>T | RNA (SNP) | VAF 7/120 reads (6%) | called by muse, mutect2
- ULK4P1 | n.228C>G | RNA (SNP) | VAF 16/105 reads (15%) | called by mutect2, varscan2
- VN1R10P | n.649C>T | RNA (SNP) | VAF 59/283 reads (21%) | catalogued as rs1022723961; called by muse, mutect2, varscan2
- YIF1B | c.58+111G>A | Intron (SNP) | VAF 52/606 reads (9%) | catalogued as rs1442571641; called by muse, mutect2
